Somatic mutation profile of tumor specimen 0DRKKI from CCDI case PBCFLY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Malignant peripheral nerve sheath tumor with rhabdomyoblastic differentiation; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 4.5 years (1,652 days).
Specimen 0DRKKI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67273b21-4918-408e-9361-44261c535dc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRKKR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79cd957d-814e-47ae-8e24-c1bb7caa34f8

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, 3'UTR 3, Nonsense Mutation 3, 3'Flank 1, Intron 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTBD11 | c.2620A>G p.K874E (on ENST00000280758 / NM_001018072.2; = p.K411E on NM_001017523.2) | Missense Mutation (SNP) | VAF 137/385 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.444); catalogued as rs1190922935; called by muse, mutect2, varscan2
- CACNA1H | c.1912G>A p.G638S | Missense Mutation (SNP) | VAF 124/174 reads (71%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs747036748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EOMES | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.52); catalogued as rs760857084; called by muse, mutect2
- COL15A1 | c.4109C>T p.A1370V | Missense Mutation (SNP) | VAF 40/584 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2
- FRY | c.4561G>A p.A1521T | Missense Mutation (SNP) | VAF 42/838 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); called by muse, mutect2
- NUTM2G | c.744G>T p.K248N | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- OVOL2 | c.254G>C p.G85A | Missense Mutation (SNP) | VAF 119/179 reads (66%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PPP1R13B | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 80/467 reads (17%) | called by muse, mutect2, varscan2
- RHOBTB2 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 214/456 reads (47%) | called by muse, varscan2
- RINL | c.991G>A p.G331S (on ENST00000591812 / NM_001195833.2; = p.G217S on NM_198445.4) | Missense Mutation (SNP) | VAF 22/802 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.254); called by muse, mutect2
- RTN1 | c.848T>C p.I283T | Missense Mutation (SNP) | VAF 35/459 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC1A6 | c.1350G>C p.Q450H | Missense Mutation (SNP) | VAF 106/524 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by mutect2, varscan2
- SLC7A8 | c.744G>C p.W248C | Missense Mutation (SNP) | VAF 111/509 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLFN14 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 18/536 reads (3%) | called by muse, mutect2
- TMEM259 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 258/463 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTF2 | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 209/453 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD2 | c.544C>A p.R182= | Silent (SNP) | VAF 120/543 reads (22%) | called by muse, mutect2, varscan2
- ASPN | c.507T>C p.L169= | Silent (SNP) | VAF 74/838 reads (9%) | called by muse, mutect2
- NIPAL1 | c.96G>A p.E32= | Silent (SNP) | VAF 55/1572 reads (3%) | called by muse, mutect2
- ORC1 | c.2289C>T p.Y763= | Silent (SNP) | VAF 118/580 reads (20%) | catalogued as COSV100856653; called by muse, mutect2, varscan2
- AATF | c.-58C>T | 5'UTR (SNP) | VAF 4/44 reads (9%) | catalogued as rs1199666895; called by muse, mutect2
- EMC3-AS1 | chr3:10007509 T>C | 3'Flank (SNP) | VAF 165/525 reads (31%) | catalogued as rs746432559; called by muse, mutect2, varscan2
- GPR55 | c.*11T>A | 3'UTR (SNP) | VAF 82/340 reads (24%) | catalogued as rs1328231794; called by muse, mutect2, varscan2
- KIR2DL3 | c.*31C>G | 3'UTR (SNP) | VAF 36/464 reads (8%) | catalogued as rs1458584961, COSV100667854; called by muse, mutect2
- KRT38 | c.*474C>T | 3'UTR (SNP) | VAF 12/191 reads (6%) | called by muse, mutect2
- MAZ | c.1043+12del | Intron (DEL) | VAF 85/181 reads (47%) | called by mutect2, varscan2
- PKD1L2 | n.2989C>T | RNA (SNP) | VAF 122/308 reads (40%) | catalogued as rs1230681972; called by muse, mutect2, varscan2
